Somatic mutation profile of tumor specimen 0DEAZ4 from CCDI case PBBPLA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 17.7 years (6,468 days).
Specimen 0DEAZ4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76adae04-27f0-42ff-aaf9-7b02d564c748.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEAYT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff9ccaba-1721-4f37-8ec3-67226df9e7a2

The open-access MAF lists 40 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Intron 5, 5'UTR 4, Splice Region 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP2C8 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 521/585 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs543793530, COSV64876837, COSV64877996; called by muse, varscan2
- GCN1 | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 665/1420 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1341306715, COSV56109840; called by muse, varscan2
- HASPIN | c.2363C>G p.T788S | Missense Mutation (SNP) | VAF 236/271 reads (87%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs117580626; called by muse, varscan2
- RBM26 | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 296/526 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV57392943; called by muse, varscan2
- RELN | c.3385T>A p.F1129I | Missense Mutation (SNP) | VAF 94/587 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1423523866; called by muse, varscan2
- TRPA1 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 308/388 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs755629572, COSV100083259; called by muse, varscan2
- VASH2 | c.279T>A p.P93= | Splice Region (SNP) | VAF 642/1448 reads (44%) | catalogued as rs760005847; called by muse, varscan2
- AFTPH | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 394/436 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, varscan2
- DNAH10 | c.5806G>C p.A1936P (on ENST00000409039; = p.A1875P on NM_207437.3) | Missense Mutation (SNP) | VAF 328/1062 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, varscan2
- FEZF2 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 398/428 reads (93%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, varscan2
- HCN4 | c.2046C>A p.Y682* | Nonsense Mutation (SNP) | VAF 64/502 reads (13%) | called by muse, varscan2
- ICE2 | c.1495G>C p.D499H | Missense Mutation (SNP) | VAF 398/442 reads (90%) | SIFT tolerated (0.08); PolyPhen benign (0.19); called by muse, varscan2
- ILDR2 | c.1852A>C p.K618Q | Missense Mutation (SNP) | VAF 304/944 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, varscan2
- NTHL1 | c.240G>T p.E80D (on ENST00000219066; = p.E72D on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 408/454 reads (90%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, varscan2
- OR10G7 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 554/698 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, varscan2
- PCDH1 | c.438T>G p.N146K | Missense Mutation (SNP) | VAF 244/271 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, varscan2
- POMC | c.613C>A p.L205M | Missense Mutation (SNP) | VAF 426/464 reads (92%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.564); called by muse, varscan2
- RIPOR2 | c.2724G>C p.R908S | Missense Mutation (SNP) | VAF 97/300 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, varscan2
- SGMS1 | c.1043A>G p.H348R | Missense Mutation (SNP) | VAF 514/568 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TP53INP2 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 705/782 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, varscan2
- VCAN | c.2480C>A p.P827H | Missense Mutation (SNP) | VAF 420/456 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CHRM3 | c.1449G>T p.L483= | Silent (SNP) | VAF 390/436 reads (89%) | called by muse, varscan2
- COL5A1 | c.2982C>A p.G994= | Silent (SNP) | VAF 343/390 reads (88%) | catalogued as rs377265020; called by muse, varscan2
- FZD8 | c.27G>A p.V9= | Silent (SNP) | VAF 300/352 reads (85%) | called by muse, varscan2
- NKD2 | c.1002C>A p.P334= | Silent (SNP) | VAF 78/464 reads (17%) | called by muse, varscan2
- OR10G7 | c.168C>A p.P56= | Silent (SNP) | VAF 548/696 reads (79%) | called by muse, varscan2
- TMEM63A | c.960C>A p.A320= | Silent (SNP) | VAF 250/520 reads (48%) | catalogued as COSV104422739; called by muse, varscan2
- TRIM58 | c.447T>A p.L149= | Silent (SNP) | VAF 460/517 reads (89%) | catalogued as COSV63569917; called by muse, varscan2
- WDR64 | c.726C>T p.V242= | Silent (SNP) | VAF 489/566 reads (86%) | called by muse, varscan2
- ZNF792 | c.1728C>T p.T576= | Silent (SNP) | VAF 328/372 reads (88%) | catalogued as COSV101289672, COSV68694388; called by muse, varscan2
- C1orf141 | c.347-7052G>A | Intron (SNP) | VAF 84/570 reads (15%) | catalogued as COSV63992740; called by muse, varscan2
- HEXB | c.-3G>T | 5'UTR (SNP) | VAF 227/258 reads (88%) | called by muse, varscan2
- KCNJ1 | c.-228C>A | 5'UTR (SNP) | VAF 244/282 reads (87%) | called by muse, varscan2
- MIIP | c.1081-79A>G | Intron (SNP) | VAF 72/147 reads (49%) | called by muse, varscan2
- NCOR2 | c.6605+52G>C | Intron (SNP) | VAF 358/724 reads (49%) | called by muse, varscan2
- NF1 | c.6922-48C>T | Intron (SNP) | VAF 94/102 reads (92%) | called by muse, varscan2
- OTC | c.*14G>T | 3'UTR (SNP) | VAF 476/554 reads (86%) | called by muse, varscan2
- SNAI1 | c.-68C>A | 5'UTR (SNP) | VAF 14/53 reads (26%) | called by muse, varscan2
- TSHR | c.692+90G>C | Intron (SNP) | VAF 398/460 reads (87%) | called by muse, varscan2
- ZNF468 | c.-53T>C | 5'UTR (SNP) | VAF 204/333 reads (61%) | called by muse, varscan2
